Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SN, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SN-01A (Primary Tumor).

[page 1 of 3]
Result Type: Surgical Pathology Report

Result Date:

**Encounter
info:**

ICD-O.3
Carcinoma, papillary renal cell
826013
Site @ Kidney NOS
C64.9
JW10/4/13

Surgical Pathology Report

Final

Surgical Pathology Report

Name:

Requested By:

DIAGNOSIS:

A. Gallbladder, cholecystectomy:

Mild chronic cholecystitis. No calculi identified.

B. Left renal mass, partial nephrectomy:

Procedure/laterality: Left partial nephrectomy.

Histologic type: Papillary renal cell carcinoma.

Nuclear grade (Fuhrman, 1-4): 2/4.

Tumor size: 4.2 x 3.8 x 3 cm.

Tumor site: Clinically lower pole.

Tumor focality: Unifocal.

Sarcomatoid features: Not identified.

Tumor necrosis: Not identified.

Microscopic tumor extension:

Extension into perinephric tissue: Not identified.

Extension beyond Gerota's fascia: Not identified.

Extension into renal sinus: Not included with the specimen.

Extension into renal vein: Not applicable.

Extension into collecting system: Not identified.

Extension into adrenal gland (if applicable): Not applicable.

Surgical margins: Negative for carcinoma.

Lymph-vascular invasion: Not identified.

Lymph nodes: Not applicable.

Pathologic findings in nonneoplastic kidney: Only minute benign kidney tissue present with no significant pathologic changes.

Pathologic staging: pT1b.

Biorepository sample (if applicable): Block B7 contains more than 90% tumor cell nuclei.

Block(s) containing malignancy suitable for additional testing: B1-7

C. Umbilical hernia sac, excision:

Membranous fragment of fibroadipose tissue with mild chronic inflammation with scarring, compatible with hernia sac.

CLINICAL INFORMATION:

[page 2 of 3]
Left renal mass.

SPECIMEN(S):

A:Gallbladder

B:Left renal mass

C:Umbilical hernia sac

GROSS DESCRIPTION:

Performed by

A. Received fresh labeled and "gallbladder," is a previously opened gallbladder, 9 x 3 cm. The serosa is glistening and smooth. The wall is uniformly 0.3 cm in thickness and the mucosa velvety soft and pale green. No calculi are received. Sampled in one cassette labeled

B. Received fresh labeled and "left renal mass".
Procedure: Partial nephrectomy.

Specimen laterality: Left.

Tumor site: Low pole clinically.

Tumor size: 4.2 x 3.8 x 3 cm.

Tumor focality: Unifocal.

Gross extent of tumor:

Extension into perinephric tissue: Not identified.

Extension beyond Gerota's fascia: Not identified.

Extension into renal sinus: Renal sinus tissue not included with specimen.

Extension into renal vein: Cannot evaluate with the specimen.

Extension into collecting system: Not identified.

Adrenal gland: Not present.

Gross notes:

Gross tumor characteristics: Mottled red-tan and gray, soft, friable.

Kidney weight: 40 g.

Kidney dimensions: The specimen has overall dimensions of 5 x 3.5 x 3.5 cm including attached fat.

Distance to margin: 0.1 cm or less in multiple areas, grossly.

Lymph nodes: None identified.

Inking details: Parenchymal margin inked black, overlying fatty soft tissue margin inked blue.

Biorepository sample submitted: Yes.

Block key for specimen B: B1) Tumor and overlying inked fatty margin; B2-B4) tumor and parenchymal margin; B5-B6) additional tumor samples; B7) mirror image of biorepository sample, IRE

C. Received fresh labeled and "umbilical hernia sac," is a rubbery pink and tan-gray portion of fibrofatty tissue, 2.7 x 1.2 x 0.8 cm. Sampled in one cassette labeled

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not

[page 3 of 3]
necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 3c4b570d-b920-44e7-811b-15762aa21d00 (TCGA-SX-A7SN.45764545-C185-4BD5-AA49-0EB0E99B984D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).